Somatic mutation profile of tumor specimen TCGA-LG-A6GG-01A (aliquot TCGA-LG-A6GG-01A-11D-A30V-10) from TCGA case TCGA-LG-A6GG, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 79.0 years (28,871 days).
Specimen TCGA-LG-A6GG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 212beb85-0f29-45d8-821e-7930ed3869dc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-LG-A6GG-10A (Blood Derived Normal), aliquot TCGA-LG-A6GG-10A-01D-A30V-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c13d153c-e424-49fa-9e3f-9dbb8a6e240d

The open-access MAF lists 216 somatic variants for this specimen: 161 protein-altering or splice-affecting, 52 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 143, Silent 52, Splice Site 9, Nonsense Mutation 5, Frame Shift Del 3, Intron 2, Splice Region 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGXT | c.614C>T p.S205L | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs180177248, CM093802, CM093803, COSV56754085; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AAK1 | c.1585C>A p.Q529K | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.761); catalogued as COSV68643855; called by muse, mutect2
- ABCA7 | c.3077G>A p.R1026H | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as rs530537679, COSV54029689; called by muse, mutect2, varscan2
- AC126283.2 | c.464T>G p.L155R | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT tolerated (0.53); PolyPhen benign (0.006); catalogued as COSV67098691; called by muse, mutect2, varscan2
- ACAD8 | c.770A>G p.N257S | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as COSV55540462; called by muse, mutect2, varscan2
- ACAP2 | c.1937T>A p.I646N | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV58751990; called by muse, mutect2, varscan2
- ADGRV1 | c.1616T>C p.L539S | Missense Mutation (SNP) | VAF 138/292 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101315503, COSV67985394; called by muse, mutect2, varscan2
- ANK1 | c.4028T>A p.L1343Q | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as COSV55881940, COSV99225206; called by muse, mutect2, varscan2
- ANKMY1 | c.1480A>T p.S494C | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as COSV56034260; called by muse, mutect2, varscan2
- ARHGAP31 | c.1111G>A p.G371S | Missense Mutation (SNP) | VAF 55/136 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.759); catalogued as rs758065077, COSV51789850, COSV99956657; called by muse, mutect2, varscan2
- ARHGAP33 | c.310C>T p.R104C | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.983); catalogued as rs374221923; called by muse, mutect2, varscan2
- ARID1A | c.4994-2A>T p.X1665_splice | Splice Site (SNP) | VAF 18/28 reads (64%) | catalogued as COSV100253620, COSV61377871; called by muse, mutect2, varscan2
- ASB15 | c.1058C>T p.A353V | Missense Mutation (SNP) | VAF 67/226 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.924); catalogued as rs1376721710, COSV51924653; called by muse, mutect2, varscan2
- ATAD2B | c.3607A>G p.M1203V | Missense Mutation (SNP) | VAF 47/153 reads (31%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs201429059; called by muse, mutect2, varscan2
- B3GAT2 | c.532C>A p.P178T | Missense Mutation (SNP) | VAF 36/120 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs778874580, COSV57770959; called by muse, mutect2, varscan2
- BCAS3 | c.2566G>A p.E856K (on ENST00000390652 / NM_001353144.2; = p.E841K on NM_017679.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.931); catalogued as COSV66774308; called by muse, mutect2, varscan2
- BPIFA1 | c.551del p.P184Lfs*28 | Frame Shift Del (DEL) | VAF 17/75 reads (23%) | catalogued as COSV62824225; called by mutect2, pindel, varscan2
- C21orf58 | c.812A>T p.Q271L | Missense Mutation (SNP) | VAF 54/76 reads (71%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.991); catalogued as COSV52449779; called by muse, mutect2, varscan2
- CACNA1E | c.2405C>A p.A802E | Missense Mutation (SNP) | VAF 54/176 reads (31%) | SIFT tolerated (0.89); PolyPhen possibly damaging (0.489); catalogued as COSV62395329; called by muse, mutect2, varscan2
- CARD11 | c.3053A>G p.Q1018R | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV67799201; called by muse, mutect2, varscan2
- CCDC27 | c.1744C>A p.L582I | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as COSV53900241; called by muse, mutect2, varscan2
- CCKBR | c.1148C>T p.A383V | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs201876764, COSV58101457; called by muse, mutect2, varscan2
- CDH7 | c.1846T>A p.C616S | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV59886522; called by muse, mutect2, varscan2
- CDHR2 | c.2935del p.A979Pfs*27 | Frame Shift Del (DEL) | VAF 20/107 reads (19%) | catalogued as COSV56134639; called by mutect2, pindel, varscan2
- CDKN1C | c.283G>A p.V95M | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs762106424, COSV57832625; called by muse, mutect2, varscan2
- CEP170B | c.623G>C p.G208A (on ENST00000453495; = p.G137A on NM_015005.3) | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.073); catalogued as COSV69024587; called by muse, mutect2
- CLCN1 | c.2363A>T p.Q788L | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.297); catalogued as CM121972, COSV58369915; called by muse, mutect2, varscan2
- CNTLN | c.1216A>T p.T406S | Missense Mutation (SNP) | VAF 146/353 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV52079249; called by muse, mutect2, varscan2
- COL26A1 | c.419G>T p.S140I (on ENST00000313669 / NM_001278563.3; = p.S138I on NM_133457.4) | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); catalogued as COSV58124756; called by muse, mutect2, varscan2
- COL6A6 | c.1450T>A p.W484R | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT tolerated (0.35); PolyPhen benign (0.025); catalogued as rs1559999816, COSV62025459; called by muse, mutect2, varscan2
- COL9A1 | c.1066-2A>T p.X356_splice | Splice Site (SNP) | VAF 108/367 reads (29%) | catalogued as COSV57883812; called by muse, mutect2, varscan2
- CPSF2 | c.852A>G p.V284= | Splice Region (SNP) | VAF 61/156 reads (39%) | catalogued as COSV54098366; called by muse, mutect2, varscan2
- CRADD | c.337A>T p.S113C | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.43); catalogued as COSV60553573; called by muse, mutect2, varscan2
- CST9L | c.229T>C p.W77R | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.309); catalogued as rs1220011256, COSV65407895; called by muse, mutect2, varscan2
- DEAF1 | c.1099C>A p.Q367K | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as COSV58607108; called by muse, mutect2, varscan2
- DIAPH2 | c.5A>C p.E2A | Missense Mutation (SNP) | VAF 70/159 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.899); catalogued as COSV61270337; called by muse, mutect2, varscan2
- DLEC1 | c.3938C>T p.P1313L | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs760972466, COSV57299881; called by muse, mutect2, varscan2
- DMRTC2 | c.740del p.P247Lfs*10 | Frame Shift Del (DEL) | VAF 26/68 reads (38%) | catalogued as COSV54186468; called by mutect2, pindel, varscan2
- DPP10 | c.1153T>A p.F385I | Missense Mutation (SNP) | VAF 45/148 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59687099, COSV59687648; called by muse, mutect2, varscan2
- EGF | c.1996A>T p.I666F | Missense Mutation (SNP) | VAF 104/171 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV54478968; called by muse, mutect2, varscan2
- FAM71B | c.1271T>A p.V424D | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.012); catalogued as COSV57229155; called by muse, mutect2, varscan2
- FANCE | c.1328A>G p.E443G | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV57689958; called by muse, mutect2, varscan2
- FBN1 | c.4585A>T p.T1529S | Missense Mutation (SNP) | VAF 64/152 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.058); catalogued as COSV57316910; called by muse, mutect2, varscan2
- FBXL4 | c.169G>T p.E57* | Nonsense Mutation (SNP) | VAF 39/83 reads (47%) | catalogued as COSV57747033; called by muse, mutect2, varscan2
- FBXO40 | c.1171C>G p.P391A | Missense Mutation (SNP) | VAF 48/109 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV57524084; called by muse, mutect2, varscan2
- FKBP4 | c.105+1G>A p.X35_splice | Splice Site (SNP) | VAF 50/126 reads (40%) | catalogued as COSV50009122; called by muse, mutect2, varscan2
- FLT1 | c.679A>T p.N227Y | Missense Mutation (SNP) | VAF 68/138 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); catalogued as COSV56728036; called by muse, mutect2, varscan2
- FMN2 | c.1625T>C p.L542P | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60430785; called by muse, mutect2, varscan2
- G2E3 | c.1709A>G p.E570G | Missense Mutation (SNP) | VAF 60/150 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV52840466; called by muse, mutect2, varscan2
- GARNL3 | c.1300A>G p.K434E | Missense Mutation (SNP) | VAF 74/168 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.055); catalogued as COSV59226407; called by muse, mutect2, varscan2
- GPR141 | c.310C>G p.L104V | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.462); catalogued as COSV57732296; called by muse, mutect2, varscan2
- GPR50 | c.1451C>A p.A484D | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.169); catalogued as rs1027467005, COSV54439154; called by muse, mutect2, varscan2
- HEATR4 | c.155G>T p.S52I | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.641); catalogued as COSV58572797; called by muse, mutect2, varscan2
- HHAT | c.814A>T p.S272C | Missense Mutation (SNP) | VAF 44/175 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV54799269; called by muse, mutect2, varscan2
- HIP1 | c.2504A>T p.Q835L | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.045); catalogued as COSV61185975; called by muse, mutect2, varscan2
- HMGB2 | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); catalogued as COSV56633605; called by muse, mutect2, varscan2
- HPSE2 | c.323T>A p.L108H | Missense Mutation (SNP) | VAF 180/210 reads (86%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); catalogued as COSV65189231; called by muse, mutect2, varscan2
- IL10RA | c.277A>T p.S93C | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.053); catalogued as COSV57140628; called by muse, mutect2, varscan2
- IWS1 | c.1930-2A>T p.X644_splice | Splice Site (SNP) | VAF 35/121 reads (29%) | catalogued as COSV54867373, COSV54868449; called by muse, mutect2, varscan2
- KIAA1191 | c.709+2T>G p.X237_splice | Splice Site (SNP) | VAF 41/153 reads (27%) | catalogued as COSV53798902; called by muse, mutect2, varscan2
- KIF5A | c.844A>T p.S282C | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54054654; called by muse, mutect2, varscan2
- KIF6 | c.2322-2A>T p.X774_splice | Splice Site (SNP) | VAF 26/72 reads (36%) | catalogued as COSV54677419; called by muse, mutect2, varscan2
- KLHL17 | c.1027G>A p.V343M | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.897); catalogued as rs748174855, COSV58531841; called by muse, mutect2, varscan2
- KLHL32 | c.359G>T p.S120I | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV65112085; called by muse, mutect2, varscan2
- KMT2C | c.9010C>G p.L3004V | Missense Mutation (SNP) | VAF 41/146 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV51440587; called by muse, mutect2, varscan2
- KRT7 | c.795G>T p.K265N | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV59331027; called by muse, mutect2, varscan2
- KRT80 | c.305A>T p.Q102L | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as COSV57549010; called by muse, mutect2, varscan2
- LRRC4C | c.413C>A p.T138N | Missense Mutation (SNP) | VAF 42/168 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.366); catalogued as COSV53425997; called by muse, mutect2, varscan2
- MAGEC2 | c.613T>A p.F205I | Missense Mutation (SNP) | VAF 58/132 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV55998284, COSV55999413; called by muse, mutect2, varscan2
- MAPK7 | c.1183A>T p.I395F | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.655); catalogued as COSV55190494; called by muse, mutect2, varscan2
- MDGA1 | c.2408A>G p.Y803C | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51796096; called by muse, mutect2, varscan2
- MDN1 | c.12328G>A p.E4110K | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as rs764180409, COSV65521724; called by muse, mutect2, varscan2
- MED23 | c.3832C>A p.L1278M | Missense Mutation (SNP) | VAF 48/135 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63432649; called by muse, mutect2, varscan2
- MERTK | c.1086G>T p.M362I | Missense Mutation (SNP) | VAF 54/135 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.037); catalogued as COSV54929085, COSV99775597; called by muse, mutect2, varscan2
- MIDEAS | c.2567A>G p.Q856R | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54094949; called by muse, mutect2, varscan2
- MRPL46 | c.406C>G p.R136G | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56900003; called by muse, mutect2, varscan2
- MYH6 | c.3614T>A p.L1205Q | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV100676732; called by muse, mutect2, varscan2
- MYO10 | c.4049C>T p.P1350L | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV57021782; called by muse, mutect2, varscan2
- MYT1 | c.296T>A p.V99E | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as COSV60505907; called by muse, mutect2, varscan2
- NEK10 | c.2606A>T p.Q869L | Missense Mutation (SNP) | VAF 50/107 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.431); catalogued as COSV99835345; called by muse, mutect2, varscan2
- NELFB | c.1144-2A>G p.X382_splice | Splice Site (SNP) | VAF 34/87 reads (39%) | catalogued as COSV58024994; called by muse, mutect2, varscan2
- NOBOX | c.1067G>T p.R356L | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56194496; called by muse, mutect2, varscan2
- NOS1 | c.4213C>T p.R1405* | Nonsense Mutation (SNP) | VAF 41/140 reads (29%) | catalogued as rs763373196, COSV57612751; called by muse, mutect2, varscan2
- NOX4 | c.283A>T p.R95W | Missense Mutation (SNP) | VAF 102/301 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54453451; called by muse, mutect2, varscan2
- NPTX1 | c.68A>T p.Q23L | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.23); catalogued as COSV60775025; called by muse, mutect2, varscan2
- NUP188 | c.3898G>A p.G1300S | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.998); catalogued as COSV65362244; called by muse, mutect2, varscan2
- NUP98 | c.3669A>T p.L1223F (on ENST00000359171 / NM_001365126.1; = p.L1206F on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV61432297; called by muse, mutect2, varscan2
- OR51D1 | c.485T>A p.L162Q | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV62913890, COSV62914209; called by muse, mutect2, varscan2
- OR51F1 | c.704T>G p.L235R | Missense Mutation (SNP) | VAF 54/180 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV58579755; called by muse, mutect2, varscan2
- OR5B12 | c.97T>A p.Y33N | Missense Mutation (SNP) | VAF 39/149 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV56905045; called by muse, mutect2, varscan2
- OR6M1 | c.751A>T p.S251C | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.71); catalogued as COSV58433615; called by muse, mutect2, varscan2
- P3H1 | c.1409A>T p.Q470L | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.105); catalogued as COSV52533803; called by muse, mutect2, varscan2
- PCDH7 | c.224T>A p.L75Q | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV62338963; called by muse, mutect2, varscan2
- PCDHGA8 | c.1498C>T p.P500S | Missense Mutation (SNP) | VAF 84/175 reads (48%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.177); catalogued as COSV53950216; called by muse, mutect2, varscan2
- PDE11A | c.2711A>T p.K904M | Missense Mutation (SNP) | VAF 79/242 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as COSV53695116; called by muse, mutect2, varscan2
- PDZRN3 | c.2922C>A p.S974R | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55199979; called by muse, mutect2, varscan2
- PDZRN3 | c.626T>G p.L209R | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55200001; called by muse, mutect2, varscan2
- PFKFB1 | c.569T>G p.L190R | Missense Mutation (SNP) | VAF 9/73 reads (12%) | PolyPhen benign (0.177); catalogued as COSV100895636, COSV66628385; called by muse, mutect2, varscan2
- PFKFB3 | c.292G>T p.V98F | Missense Mutation (SNP) | VAF 5/40 reads (13%) | PolyPhen possibly damaging (0.543); catalogued as COSV57988813; called by muse, mutect2
- PIP5K1C | c.1208A>T p.Y403F | Missense Mutation (SNP) | VAF 45/99 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.361); catalogued as COSV58952422; called by muse, mutect2, varscan2
- PKHD1 | c.1354T>A p.Y452N | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61875940; called by muse, mutect2, varscan2
- PKHD1L1 | c.7140A>C p.E2380D | Missense Mutation (SNP) | VAF 78/197 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.042); catalogued as COSV65743110; called by muse, mutect2, varscan2
- PLEKHM1 | c.1163A>G p.Q388R | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.101); catalogued as COSV69598883; called by muse, mutect2, varscan2
- PPP1R13B | c.2014C>T p.P672S | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52451523; called by muse, mutect2, varscan2
- PRDX4 | c.466C>G p.H156D | Missense Mutation (SNP) | VAF 216/547 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65018678; called by muse, mutect2, varscan2
- PSKH2 | c.769A>T p.S257C | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.534); catalogued as COSV52610551; called by muse, varscan2
- PTCHD4 | c.1895T>A p.L632Q | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59784478; called by muse, mutect2, varscan2
- PTGIR | c.1006C>T p.P336S | Missense Mutation (SNP) | VAF 48/100 reads (48%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.177); catalogued as rs916113670, COSV52192112; called by muse, mutect2, varscan2
- PTPRT | c.1973T>A p.L658H | Missense Mutation (SNP) | VAF 56/164 reads (34%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.984); catalogued as COSV61981884; called by muse, mutect2, varscan2
- RAP1A | c.460G>A p.V154I | Missense Mutation (SNP) | VAF 53/141 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.069); catalogued as COSV62727736; called by muse, mutect2, varscan2
- RBSN | c.74C>A p.S25Y | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV53793076; called by muse, mutect2
- REV3L | c.6619A>T p.R2207* | Nonsense Mutation (SNP) | VAF 35/78 reads (45%) | catalogued as COSV62619061; called by muse, mutect2, varscan2
- RITA1 | c.449G>T p.G150V | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.074); catalogued as rs780174678, COSV55321617; called by muse, mutect2, varscan2
- RNF212 | c.248T>A p.I83N | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as COSV61364555; called by muse, mutect2, varscan2
- ROCK2 | c.3280-2A>T p.X1094_splice | Splice Site (SNP) | VAF 58/210 reads (28%) | catalogued as COSV59957346; called by muse, mutect2, varscan2
- RP1 | c.268C>G p.H90D | Missense Mutation (SNP) | VAF 31/55 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs779243716, COSV55116959; called by muse, mutect2, varscan2
- RPS6KA2 | c.1225A>T p.I409F | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (0.72); PolyPhen benign (0.01); catalogued as COSV55820774, COSV55830896; called by muse, mutect2, varscan2
- SAMD9L | c.1553A>C p.Q518P | Missense Mutation (SNP) | VAF 69/200 reads (35%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.667); catalogued as COSV59081625; called by muse, mutect2, varscan2
- SCAF8 | c.1978C>A p.P660T | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV63200232; called by muse, mutect2, varscan2
- SCAP | c.1741C>A p.P581T | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.03); catalogued as COSV55561400; called by muse, mutect2, varscan2
- SCNN1G | c.263A>T p.H88L | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.138); catalogued as COSV55598948; called by muse, mutect2, varscan2
- SEMA6A | c.2308C>T p.P770S | Missense Mutation (SNP) | VAF 42/76 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV56711303; called by muse, mutect2, varscan2
- SEPTIN4 | c.887T>A p.L296H | Missense Mutation (SNP) | VAF 52/181 reads (29%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.321); catalogued as COSV58727918; called by muse, mutect2, varscan2
- SERTAD3 | c.212T>A p.L71Q | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.11); catalogued as COSV59324938; called by muse, mutect2, varscan2
- SESN3 | c.1442T>C p.L481P | Missense Mutation (SNP) | VAF 34/141 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53585003; called by muse, mutect2, varscan2
- SIAH1 | c.356A>C p.E119A | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.779); catalogued as COSV53522574; called by muse, mutect2, varscan2
- SIPA1L2 | c.4838G>T p.C1613F | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.273); catalogued as COSV53390649; called by muse, mutect2, varscan2
- SLC17A3 | c.759+1G>A p.X253_splice | Splice Site (SNP) | VAF 40/152 reads (26%) | catalogued as rs773136308, COSV57760036; called by muse, mutect2, varscan2
- SLC1A6 | c.1462G>T p.E488* | Nonsense Mutation (SNP) | VAF 39/134 reads (29%) | catalogued as COSV55670467, COSV55670568; called by muse, mutect2, varscan2
- SLC29A4 | c.674C>G p.P225R | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.34); catalogued as rs757496111, COSV51874225; called by muse, mutect2, varscan2
- SLC7A8 | c.156C>G p.N52K | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57554117; called by muse, mutect2, varscan2
- SMG1 | c.1633G>T p.A545S | Missense Mutation (SNP) | VAF 89/197 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.289); catalogued as COSV67171422; called by muse, mutect2, varscan2
- SPTBN5 | c.131A>G p.H44R | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.73); catalogued as COSV58020770; called by muse, mutect2, varscan2
- ST18 | c.2179C>A p.P727T | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV52494500; called by muse, mutect2, varscan2
- STAC2 | c.757G>T p.G253W | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.635); catalogued as COSV61065544; called by muse, mutect2, varscan2
- SV2A | c.1511A>T p.Q504L | Missense Mutation (SNP) | VAF 48/185 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.224); catalogued as COSV64964801; called by muse, mutect2, varscan2
- TBC1D28 | c.323G>A p.G108D | Missense Mutation (SNP) | VAF 50/123 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs758826020, COSV61507627; called by muse, mutect2, varscan2
- TCN2 | c.160A>G p.I54V | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as COSV53191471; called by muse, mutect2, varscan2
- TLL1 | c.2295T>A p.N765K | Missense Mutation (SNP) | VAF 17/179 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV50280737; called by muse, mutect2, varscan2
- TPP2 | c.1542T>A p.N514K | Missense Mutation (SNP) | VAF 57/157 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.038); catalogued as COSV65752709; called by muse, mutect2, varscan2
- TRERF1 | c.3134A>G p.K1045R | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV61671765; called by muse, mutect2, varscan2
- TRIM4 | c.590T>C p.M197T | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0.05); catalogued as COSV62469210; called by muse, mutect2, varscan2
- TRIM52 | c.847C>A p.L283I | Missense Mutation (SNP) | VAF 41/211 reads (19%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.014); catalogued as COSV59844271; called by muse, mutect2, varscan2
- TSHZ3 | c.1939A>C p.S647R | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV53671869; called by muse, mutect2, varscan2
- TTN | c.4694T>C p.V1565A (on ENST00000591111; = p.V1519A on NM_003319.4) | Missense Mutation (SNP) | VAF 20/93 reads (22%) | PolyPhen benign (0.033); catalogued as rs1441856975, COSV100609441, COSV60069057; called by muse, mutect2, varscan2
- TUBB1 | c.683T>A p.L228Q | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV53886805, COSV53887604; called by muse, mutect2, varscan2
- TUBGCP6 | c.716C>T p.A239V | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.543); catalogued as rs1405343723, COSV50546065; called by muse, mutect2, varscan2
- UBQLN1 | c.1174C>A p.Q392K | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.263); catalogued as COSV57408007; called by muse, mutect2, varscan2
- WFDC3 | c.172A>C p.T58P | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.229); catalogued as COSV54785149; called by muse, mutect2, varscan2
- ZDBF2 | c.6980A>T p.D2327V | Missense Mutation (SNP) | VAF 70/276 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as COSV65626065; called by muse, mutect2, varscan2
- ZFP42 | c.689C>A p.S230* | Nonsense Mutation (SNP) | VAF 39/66 reads (59%) | catalogued as COSV58817432, COSV58817459, COSV58818701; called by muse, mutect2, varscan2
- ZFR2 | c.1720C>A p.P574T | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); catalogued as COSV53598756; called by muse, mutect2
- ZNF101 | c.1004A>G p.E335G | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.077); catalogued as COSV58908978; called by muse, mutect2, varscan2
- ZNF174 | c.1069G>A p.G357R | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.557); catalogued as rs753184330, COSV51902673; called by muse, mutect2, varscan2
- ZNF180 | c.1171A>C p.S391R | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT tolerated (0.35); PolyPhen benign (0.015); catalogued as COSV55421302; called by muse, mutect2
- ZNF536 | c.2440G>T p.G814W | Missense Mutation (SNP) | VAF 56/121 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV100835397; called by muse, mutect2, varscan2
- ZNF536 | c.2441G>T p.G814V | Missense Mutation (SNP) | VAF 52/118 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as COSV62826344, COSV62830641; called by muse, mutect2, varscan2
- ZNF773 | c.1147G>C p.G383R | Missense Mutation (SNP) | VAF 52/124 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56588652; called by muse, mutect2, varscan2
- ZNF793 | c.211G>A p.A71T | Missense Mutation (SNP) | VAF 56/120 reads (47%) | SIFT tolerated (0.5); PolyPhen benign (0.011); catalogued as rs766584030, COSV71324982; called by muse, mutect2, varscan2
- IGKV3-15 | c.331T>A p.Y111N | Missense Mutation (SNP) | VAF 225/1493 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MLLT6 | c.707G>C p.R236T | Missense Mutation (SNP) | VAF 48/110 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- AARS1 | c.1245T>C p.Y415= | Silent (SNP) | VAF 31/42 reads (74%) | catalogued as rs755334113, COSV55747437; called by muse, mutect2, varscan2
- ABLIM2 | c.1116C>T p.S372= | Silent (SNP) | VAF 22/83 reads (27%) | catalogued as COSV56404608; called by muse, mutect2, varscan2
- AHI1 | c.3102T>G p.T1034= | Silent (SNP) | VAF 35/104 reads (34%) | catalogued as COSV55627930; called by muse, mutect2, varscan2
- ARMC3 | c.189C>T p.L63= | Silent (SNP) | VAF 82/161 reads (51%) | catalogued as rs570281393, COSV53061542; called by muse, mutect2, varscan2
- ATP2B1 | c.2511C>T p.S837= | Silent (SNP) | VAF 54/131 reads (41%) | catalogued as rs112647159, COSV53807620; called by muse, mutect2, varscan2
- CACNG8 | c.849G>T p.P283= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as COSV54414753; called by muse, mutect2, varscan2
- CDH11 | c.1140C>T p.P380= | Silent (SNP) | VAF 40/55 reads (73%) | catalogued as rs1567506882, COSV51762085; called by muse, mutect2, varscan2
- CHD7 | c.7413A>G p.S2471= | Silent (SNP) | VAF 65/131 reads (50%) | catalogued as COSV71110620; called by muse, mutect2, varscan2
- CNGA4 | c.333C>T p.R111= | Silent (SNP) | VAF 21/72 reads (29%) | catalogued as rs878876329, COSV66005939; called by muse, mutect2, varscan2
- CRNN | c.1194A>T p.T398= | Silent (SNP) | VAF 15/73 reads (21%) | catalogued as COSV55122058; called by muse, mutect2, varscan2
- DNAJC2 | c.1749G>A p.A583= | Silent (SNP) | VAF 53/147 reads (36%) | catalogued as rs772238229, COSV50786132; called by muse, mutect2, varscan2
- EAF1 | c.417T>G p.P139= | Silent (SNP) | VAF 28/70 reads (40%) | catalogued as COSV67657262; called by muse, mutect2, varscan2
- EMP3 | c.423G>T p.L141= | Silent (SNP) | VAF 3/36 reads (8%) | catalogued as COSV99507361; called by muse, mutect2
- ERC1 | c.777A>C p.V259= | Silent (SNP) | VAF 15/67 reads (22%) | catalogued as COSV61695037; called by muse, mutect2, varscan2
- FREM2 | c.1242A>C p.V414= | Silent (SNP) | VAF 32/84 reads (38%) | catalogued as COSV54838100; called by muse, mutect2, varscan2
- FSD2 | c.1506T>C p.T502= | Silent (SNP) | VAF 32/72 reads (44%) | catalogued as rs749681750, COSV58010153; called by muse, mutect2, varscan2
- FZD9 | c.969C>T p.F323= | Silent (SNP) | VAF 17/56 reads (30%) | catalogued as rs144961735; called by muse, mutect2, varscan2
- GFUS | c.81A>C p.V27= | Silent (SNP) | VAF 41/89 reads (46%) | catalogued as COSV71254276; called by muse, mutect2, varscan2
- GPR156 | c.2115C>G p.A705= | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as COSV59939945; called by muse, mutect2, varscan2
- H2BC6 | c.90C>G p.R30= | Silent (SNP) | VAF 40/153 reads (26%) | catalogued as COSV61591093; called by muse, mutect2, varscan2
- HAS2 | c.1542T>A p.V514= | Silent (SNP) | VAF 46/112 reads (41%) | catalogued as COSV58264146; called by muse, varscan2
- KCNK3 | c.60G>T p.L20= | Silent (SNP) | VAF 19/65 reads (29%) | catalogued as COSV57192599; called by muse, mutect2, varscan2
- LCT | c.2907G>A p.L969= | Silent (SNP) | VAF 17/80 reads (21%) | catalogued as COSV51549560; called by muse, mutect2, varscan2
- LENEP | c.126C>A p.T42= | Silent (SNP) | VAF 16/57 reads (28%) | catalogued as COSV52697075; called by muse, mutect2, varscan2
- MAD1L1 | c.954G>A p.E318= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as COSV56234864; called by muse, varscan2
- MC4R | c.453C>T p.I151= | Silent (SNP) | VAF 20/61 reads (33%) | catalogued as rs142925940; called by muse, mutect2, varscan2
- MUC16 | c.12897T>A p.I4299= | Silent (SNP) | VAF 23/29 reads (79%) | catalogued as rs1220252762, COSV67466829; called by muse, mutect2, varscan2
- MYO7A | c.162G>A p.T54= | Silent (SNP) | VAF 47/78 reads (60%) | catalogued as rs782185833, COSV68684708; called by muse, mutect2, varscan2
- NCKAP1 | c.597T>C p.H199= | Silent (SNP) | VAF 72/269 reads (27%) | catalogued as COSV62941207; called by muse, mutect2, varscan2
- NPSR1 | c.1056T>A p.A352= | Silent (SNP) | VAF 66/228 reads (29%) | catalogued as COSV63106723; called by muse, mutect2, varscan2
- OR5H1 | c.231G>T p.V77= | Silent (SNP) | VAF 214/557 reads (38%) | catalogued as COSV63402385; called by muse, mutect2, varscan2
- OR8S1 | c.282A>G p.V94= | Silent (SNP) | VAF 29/69 reads (42%) | catalogued as COSV59599881; called by muse, mutect2
- PCDHGB2 | c.963A>C p.A321= | Silent (SNP) | VAF 37/175 reads (21%) | catalogued as COSV53950192; called by muse, mutect2, varscan2
- PGR | c.753A>G p.G251= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as COSV54801567; called by muse, mutect2, varscan2
- PHIP | c.2781G>C p.V927= | Silent (SNP) | VAF 43/91 reads (47%) | catalogued as COSV51504685; called by muse, mutect2, varscan2
- PKD1L1 | c.5037A>T p.A1679= | Silent (SNP) | VAF 106/308 reads (34%) | catalogued as COSV56965254; called by muse, mutect2, varscan2
- PLD5 | c.1248T>C p.F416= (on ENST00000442594; = p.F354= on NM_001195811.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 27/117 reads (23%) | catalogued as COSV59146101; called by muse, mutect2, varscan2
- PRDM1 | c.1608A>T p.A536= | Silent (SNP) | VAF 47/118 reads (40%) | catalogued as COSV64845281; called by muse, mutect2, varscan2
- REV3L | c.5754G>A p.K1918= | Silent (SNP) | VAF 34/70 reads (49%) | catalogued as COSV62619070; called by muse, mutect2, varscan2
- RNF6 | c.870A>T p.T290= | Silent (SNP) | VAF 36/100 reads (36%) | catalogued as COSV60418955; called by muse, mutect2, varscan2
- ROS1 | c.3090A>T p.T1030= | Silent (SNP) | VAF 40/93 reads (43%) | catalogued as COSV63855325; called by muse, mutect2, varscan2
- SEMA3A | c.615T>G p.L205= | Silent (SNP) | VAF 62/208 reads (30%) | catalogued as COSV54870879; called by muse, mutect2, varscan2
- SFTPA2 | c.654T>G p.G218= | Silent (SNP) | VAF 246/302 reads (81%) | catalogued as COSV64882497; called by muse, mutect2, varscan2
- SLC25A24 | c.1014A>G p.E338= | Silent (SNP) | VAF 26/133 reads (20%) | catalogued as COSV51447850; called by muse, mutect2, varscan2
- STYXL2 | c.1758G>C p.L586= | Silent (SNP) | VAF 37/108 reads (34%) | catalogued as COSV54805266; called by muse, mutect2, varscan2
- TGFBRAP1 | c.1728A>T p.P576= | Silent (SNP) | VAF 46/149 reads (31%) | catalogued as COSV51512257; called by muse, mutect2, varscan2
- THBS2 | c.1089A>G p.P363= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as COSV64678942; called by muse, mutect2, varscan2
- TMCC3 | c.1053A>T p.T351= | Silent (SNP) | VAF 30/51 reads (59%) | catalogued as COSV54154552; called by muse, mutect2
- USP53 | c.1203G>A p.K401= | Silent (SNP) | VAF 180/609 reads (30%) | catalogued as COSV56793727; called by muse, mutect2, varscan2
- ZFP91 | c.324G>A p.K108= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as COSV60158970; called by muse, mutect2, varscan2
- ZMYM4 | c.4335A>G p.K1445= | Silent (SNP) | VAF 27/80 reads (34%) | catalogued as rs758242667, COSV58909124, COSV58910802; called by muse, mutect2, varscan2
- ZNF609 | c.2538T>G p.S846= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as rs372733652; called by muse, mutect2, varscan2
- AIRE | c.880-41A>G | Intron (SNP) | VAF 31/39 reads (79%) | catalogued as COSV99381232; called by muse, mutect2, varscan2
- C20orf204 | c.*182_*195del | 3'UTR (DEL) | VAF 35/56 reads (63%) | called by mutect2, pindel, varscan2
- EFCAB2 | c.781+3670T>A | Intron (SNP) | VAF 75/325 reads (23%) | catalogued as COSV63656418; called by muse, mutect2, varscan2
